Somatic mutation profile of tumor specimen 0E1MC1 from CCDI case PBCVWA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1MC1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8702355d-e7a3-4178-9a89-64a73c295bf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0YD5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51a8a099-bea0-4c62-829d-ebd99f32b5d0

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP4E1 | c.2227C>G p.Q743E | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555462180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV71406297; called by muse, mutect2, varscan2
- LRRC7 | c.3535G>T p.D1179Y (on ENST00000651989 / NM_001370785.2; = p.D1146Y on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV50412151, COSV50457035; called by muse, mutect2, varscan2
- SORCS3 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV63802669; called by mutect2, varscan2
- UNC5A | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs780569422, COSV99994516; called by muse, mutect2, varscan2
- OR6C2 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SMARCB1 | c.363C>A p.S121R (on ENST00000263121; = p.C167* on NM_003073.5) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZAN | c.1655G>C p.G552A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.85); called by muse, mutect2
- GP5 | c.87C>T p.F29= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs564091697; called by muse, mutect2, varscan2
- HDAC6 | c.3585C>T p.L1195= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- TIRAP | c.102G>A p.K34= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV67023819; called by muse, mutect2
- SEMA4C | c.-12G>A | 5'UTR (SNP) | VAF 30/47 reads (64%) | catalogued as rs763676752; called by muse, mutect2, varscan2
- ZG16B | c.263+17T>A | Intron (SNP) | VAF 3/21 reads (14%) | called by mutect2, varscan2
